Gene-level copy-number profile of tumor specimen TCGA-A6-2677-01A from TCGA case TCGA-A6-2677, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.8 years (25,143 days).
Specimen TCGA-A6-2677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.bb18084d-c9cd-4cec-a93d-56e910975d8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2677-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (3 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1a6dc2a-4289-4868-95c1-b68676df0bb9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 6,668; copy number 2: 42,326; copy number 3: 9,181; copy number 4: 991; copy number 5: 622; copy number 6: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-2677-01A-01D-A274-01): tumor purity 0.88, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 652 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:27,311,482–27,812,640, 17 genes, copy number 6 (within-gene range 4–6): PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P.
- chr8:30,237,382–30,658,236, 13 genes, copy number 6: HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P.
- chr8:38,030,534–39,417,378, 43 genes, copy number 5 (within-gene range 3–5): EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:100,257,060–101,169,629, 29 genes, copy number 5: RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1.
- chr17:66,964,707–83,095,122, 550 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,668. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
